Somatic mutation profile of tumor specimen 0DFRU0 from CCDI case PBBSME, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.5 years (6,013 days).
Specimen 0DFRU0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9a405034-64e7-4c1e-8711-0b0a56c48b34.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFRU1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/42a9e8b3-3f1e-47e9-8ca4-8bb22cd0b7e5

The open-access MAF lists 18 somatic variants for this specimen: 11 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 5, Nonsense Mutation 3, Intron 1, 5'UTR 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DENND5A | c.2314C>T p.R772* | Nonsense Mutation (SNP) | VAF 291/650 reads (45%) | catalogued as rs1057519563, COSV60232046; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CES1 | c.1045G>A p.G349R | Missense Mutation (SNP) | VAF 259/583 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757978769, COSV62090579; called by muse, mutect2, varscan2
- FTMT | c.684C>A p.Y228* | Nonsense Mutation (SNP) | VAF 274/603 reads (45%) | catalogued as COSV58421023; called by muse, mutect2, varscan2
- POLQ | c.166G>T p.E56* | Nonsense Mutation (SNP) | VAF 142/276 reads (51%) | catalogued as COSV51762174; called by muse, mutect2, varscan2
- SRCAP | c.544C>T p.R182W | Missense Mutation (SNP) | VAF 182/435 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52672551; called by muse, mutect2, varscan2
- ACAD8 | c.705G>T p.K235N | Missense Mutation (SNP) | VAF 103/220 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- APOBEC3D | c.47_48del p.T16Ifs*6 | Frame Shift Del (DEL) | VAF 122/692 reads (18%) | called by pindel, varscan2
- DDX42 | c.2404G>A p.G802S | Missense Mutation (SNP) | VAF 285/936 reads (30%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NDN | c.161C>A p.A54D | Missense Mutation (SNP) | VAF 195/398 reads (49%) | SIFT tolerated (0.34); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- NFKBIA | c.337-3T>G | Splice Region (SNP) | VAF 126/244 reads (52%) | called by muse, mutect2, varscan2
- SCN7A | c.1056G>C p.Q352H | Missense Mutation (SNP) | VAF 126/566 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HS3ST4 | c.876C>T p.T292= | Silent (SNP) | VAF 54/887 reads (6%) | called by muse, mutect2
- LRRIQ4 | c.354C>T p.H118= | Silent (SNP) | VAF 41/807 reads (5%) | catalogued as rs776478957, COSV61618617; called by muse, mutect2
- PRPF4B | c.1701A>C p.P567= | Silent (SNP) | VAF 71/643 reads (11%) | called by muse, mutect2, varscan2
- SPDYA | c.543T>C p.C181= | Silent (SNP) | VAF 77/414 reads (19%) | called by muse, mutect2, varscan2
- UGT3A2 | c.417C>T p.F139= | Silent (SNP) | VAF 210/467 reads (45%) | catalogued as rs765252565, COSV56928250; called by muse, mutect2, varscan2
- KCNA5 | c.-20_-17delinsGG | 5'UTR (DEL) | VAF 108/322 reads (34%) | called by pindel, varscan2*
- KIF27 | c.3722-20G>A | Intron (SNP) | VAF 62/145 reads (43%) | called by muse, mutect2, varscan2
